Somatic mutation profile of tumor specimen TCGA-L5-A4OQ-01A (aliquot TCGA-L5-A4OQ-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 75.5 years (27,565 days).
Specimen TCGA-L5-A4OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef64b7ba-90db-4708-9dbe-84bc18f3f666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OQ-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OQ-11A-12D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1949b510-62ed-468c-9f97-d5236862f664

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 96/199 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs201022450; called by muse, mutect2, varscan2
- CLDN16 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs549642537, COSV53227390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as rs1197962947; called by muse, mutect2
- ECEL1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.071); catalogued as rs765760240; called by muse, mutect2, varscan2
- ELOVL3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149375895; called by muse, mutect2, varscan2
- GABRA3 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs201199669; called by muse, mutect2, varscan2
- HIVEP2 | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204928607; called by muse, mutect2, varscan2
- IRX5 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV58058605, COSV58059066; called by muse, mutect2, varscan2
- KIF1A | c.3442G>A p.G1148S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225778411; called by muse, mutect2
- MAP3K5 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1479028065, COSV62890509; called by muse, mutect2, varscan2
- MIPEP | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs761087143, COSV66300036, COSV66300363; called by muse, mutect2, varscan2
- PCDHAC2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53863442; called by muse, mutect2, varscan2
- PIK3R1 | c.1300G>A p.D434N (on ENST00000521381 / NM_181523.3; = p.D164N on NM_181504.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99160453; called by muse, mutect2, varscan2
- PXDN | c.886T>G p.L296V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV53225843; called by muse, mutect2, varscan2
- RNASEL | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755669893; called by muse, mutect2, varscan2
- SGSM2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs774147456, COSV52160502; called by muse, mutect2, varscan2
- ZNF185 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs895396553, COSV59274098; called by muse, mutect2, varscan2
- AP002512.3 | c.1093A>G p.R365G | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- CCDC62 | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CD1B | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CDC45 | c.174del p.E59Kfs*17 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- CDH9 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2
- CTSK | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CYP4F8 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND1A | c.2681A>C p.N894T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAH9 | c.9607C>T p.P3203S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- E2F8 | c.2036del p.P679Qfs*2 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- HHIP | c.1376dup p.N459Kfs*17 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); called by muse, mutect2
- KIF1A | c.3441C>A p.N1147K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2
- KMT2C | c.12634A>T p.K4212* | Nonsense Mutation (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- LRP5 | c.2611_2627dup p.R877Pfs*19 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- LRRN1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MAJIN | c.101+1_101+13del p.X34_splice | Splice Site (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel
- MOV10 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- MUC4 | c.15242C>T p.P5081L (on ENST00000463781 / NM_018406.7; = p.P845L on NM_004532.6) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO1F | c.2390T>C p.V797A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR10A5 | c.886A>T p.S296C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, varscan2
- PCDH15 | c.2467A>C p.T823P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PCSK2 | c.1733C>G p.A578G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- PHF12 | c.2844C>A p.H948Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRKDC | c.5275_5277del p.L1759del | In Frame Del (DEL) | VAF 14/39 reads (36%) | called by pindel, varscan2
- PSG3 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RPUSD2 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TREML1 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- USP18 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF534 | c.582T>G p.I194M (on ENST00000332323 / NM_001143939.3; = p.I181M on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.089); called by muse, mutect2
- ZNF701 | c.469G>C p.E157Q (on ENST00000301093; = p.E91Q on NM_018260.3) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CEP192 | c.3639C>A p.G1213= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- DCC | c.3180A>C p.G1060= | Silent (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- DYSF | c.1236G>A p.K412= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV50286651; called by muse, mutect2, varscan2
- EPHA1 | c.480G>A p.V160= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs750278271; called by muse, mutect2, varscan2
- FANCM | c.1246C>T p.L416= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- GRIN2A | c.1191C>T p.S397= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1231295919, COSV58025607, COSV58031282; ClinVar: likely benign; called by muse, mutect2
- LFNG | c.936C>T p.H312= (on ENST00000222725 / NM_001040167.2; = p.H183= on NM_002304.2) | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- MIDN | c.807C>A p.I269= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs762023310; called by muse, mutect2, varscan2
- MUC16 | c.17532C>A p.I5844= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2
- OR51B4 | c.570G>A p.T190= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs116689629, COSV66517115; called by muse, mutect2
- PHRF1 | c.879G>A p.T293= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs758686517; called by muse, mutect2
- SIPA1L2 | c.607T>C p.L203= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- THOC7 | c.337C>A p.R113= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.513T>C p.Y171= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1200402356; called by muse, mutect2
- PRND | chr20:4732543 G>C | 3'Flank (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- RN7SL484P | n.179G>A | RNA (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
